Somatic mutation profile of tumor specimen TCGA-CQ-6225-01A (aliquot TCGA-CQ-6225-01A-11D-1912-08) from TCGA case TCGA-CQ-6225, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.7 years (23,988 days).
Specimen TCGA-CQ-6225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3582223-fb71-4932-88d2-8fc2c20a8777.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6225-10A (Blood Derived Normal), aliquot TCGA-CQ-6225-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f0d77db-02da-464e-ab75-90de8f8894bd

The open-access MAF lists 161 somatic variants for this specimen: 115 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 39, Frame Shift Del 11, Intron 5, In Frame Del 5, Nonsense Mutation 5, Splice Site 4, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2, varscan2
- TP53 | c.527G>C p.C176S | Missense Mutation (SNP) | VAF 29/39 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52660760, COSV52661329, COSV52678029; called by muse, mutect2, varscan2
- ABCG4 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100267043; called by muse, mutect2, varscan2
- ABLIM3 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV100448790; called by muse, mutect2, varscan2
- ACSS3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747109152, COSV99698558, COSV99699436; called by muse, mutect2, varscan2
- ADCK1 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV99452636; called by muse, mutect2, varscan2
- ASB15 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs974624560, COSV51924013; called by muse, mutect2, varscan2
- ASB15 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV99306974; called by muse, mutect2, varscan2
- ATP8A1 | c.1926G>C p.E642D | Missense Mutation (SNP) | VAF 94/108 reads (87%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV100047290; called by muse, mutect2, varscan2
- ATRNL1 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV100746900; called by muse, mutect2, varscan2
- BRINP1 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99776880; called by muse, mutect2
- C5orf38 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1287382787, COSV100121907; called by muse, mutect2, varscan2
- CAND1 | c.2368C>G p.L790V | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV73389586; called by muse, mutect2, varscan2
- CDH10 | c.2118T>A p.D706E | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV100053084; called by muse, mutect2, varscan2
- CDK5RAP1 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1292330159, COSV100212290; called by muse, mutect2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CLCNKB | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs1385714869, COSV100990470; called by muse, mutect2, varscan2
- CNOT3 | c.2022C>G p.I674M | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99652320; called by muse, mutect2, varscan2
- COL10A1 | c.272A>C p.Q91P | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99684455; called by muse, mutect2, varscan2
- CRIM1 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1476784599, COSV99754449; called by muse, mutect2, varscan2
- CSMD2 | c.1177T>G p.W393G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595125; called by muse, mutect2
- CYP46A1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs775557276, COSV99952866; called by muse, mutect2, varscan2
- DEFB123 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 169/426 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV100889867; called by muse, mutect2, varscan2
- DNAH8 | c.10642G>A p.E3548K | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59486562; called by muse, mutect2, varscan2
- DNAI4 | c.2159T>C p.F720S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100925500; called by muse, mutect2, varscan2
- DOK4 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769448574, COSV54674292, COSV99538465; called by muse, mutect2, varscan2
- ELMO2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99282036; called by muse, mutect2, varscan2
- EME1 | c.781T>G p.L261V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869142; called by muse, mutect2
- EML5 | c.5845G>A p.V1949I (on ENST00000380664; = p.V1957I on NM_183387.3) | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV99193252; called by muse, mutect2, varscan2
- ETFBKMT | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV99861698; called by muse, mutect2, varscan2
- FAM184A | c.2871G>T p.K957N | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100138351; called by muse, mutect2, varscan2
- FAM187B | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100220079, COSV61201291; called by muse, mutect2, varscan2
- FAM83H | c.2681C>G p.T894S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as rs782743196, COSV100568094; called by muse, mutect2, varscan2
- FYB1 | c.1862A>G p.D621G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV100686364; called by muse, mutect2, varscan2
- GARRE1 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1383043124, COSV55101148; called by muse, mutect2, varscan2
- GPR21 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV101016518; called by muse, mutect2, varscan2
- GRM1 | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99268841; called by muse, mutect2, varscan2
- H4C7 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV99769269; called by muse, mutect2, varscan2
- HERC2 | c.10230-1G>C p.X3410_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99876654; called by muse, mutect2, varscan2
- HIRIP3 | c.65+1G>A p.X22_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99663319; called by muse, mutect2, varscan2
- HTR3D | c.1236G>C p.E412D (on ENST00000382489 / NM_001163646.2; = p.E237D on NM_182537.3) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV100488336, COSV61915422; called by muse, mutect2, varscan2
- IFFO1 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100351363; called by muse, mutect2, varscan2
- IGKJ3 | c.19G>T p.G7W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs529908096; called by muse, mutect2, varscan2
- KCNMB2 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100844067, COSV64202141; called by muse, mutect2, varscan2
- KRT33A | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 173/218 reads (79%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99145009; called by muse, mutect2, varscan2
- LARP6 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV100151066; called by muse, mutect2, varscan2
- LNP1 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 86/128 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs755197709, COSV101051365; called by muse, mutect2, varscan2
- MARCHF7 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV99374106; called by muse, mutect2, varscan2
- MFSD1 | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99964077; called by muse, mutect2
- MGAM | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs782236312, COSV71885941; called by muse, mutect2, varscan2
- MGMT | c.688T>G p.S230A (on ENST00000306010; = p.S199A on NM_002412.5) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100024132; called by muse, mutect2, varscan2
- MMP20 | c.800A>C p.Q267P | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52777600, COSV99497970; called by muse, mutect2, varscan2
- MMS22L | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV99247707; called by muse, mutect2, varscan2
- MOAP1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV52093035, COSV99365799; called by muse, mutect2, varscan2
- MOS | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs752885822, COSV61336588; called by muse, mutect2, varscan2
- MRPL1 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1450002556, COSV100214037; called by muse, mutect2
- MYOG | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99614059; called by muse, mutect2, varscan2
- NFXL1 | c.2562G>T p.Q854H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101040626; called by muse, mutect2, varscan2
- NRXN1 | c.4365G>T p.E1455D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.695); catalogued as COSV100640719; called by muse, mutect2, varscan2
- NUTM2G | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.227); catalogued as COSV100672967; called by muse, mutect2, varscan2
- OR2B6 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV55129386, COSV99773820; called by muse, mutect2
- OR56A1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs139301829; called by muse, mutect2, varscan2
- OR6C2 | c.807_810del p.N269Kfs*14 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs780926843; called by pindel, varscan2
- OTOGL | c.6883G>A p.G2295S (on ENST00000547103; = p.G2286S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781121960, COSV54016640, COSV54020198; called by muse, mutect2, varscan2
- PCDHA13 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56524837; called by muse, mutect2, varscan2
- PCDHA7 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65343835; called by muse, mutect2, varscan2
- PCDHGA1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.168); catalogued as COSV100966079, COSV65296362; called by muse, mutect2, varscan2
- PDE1C | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1360269609, COSV58507262; called by muse, mutect2, varscan2
- PEX5L | c.188T>G p.M63R | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99829920; called by muse, mutect2
- PIK3AP1 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100226210; called by muse, mutect2, varscan2
- PLBD2 | c.537G>C p.W179C | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108334, COSV99785504; called by muse, mutect2, varscan2
- POLR2B | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs568324163, COSV58901376; called by muse, mutect2, varscan2
- PRICKLE1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV100566669; called by muse, mutect2, varscan2
- PRKD3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV52212992, COSV99306896; called by muse, mutect2, varscan2
- RANBP17 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV101206379, COSV66653705; called by muse, mutect2, varscan2
- RELN | c.8275-2A>T p.X2759_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as rs755251536, COSV100634913; called by muse, mutect2, varscan2
- RNF182 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.939); catalogued as COSV101337971; called by muse, mutect2
- RNMT | c.675T>A p.C225* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100054950; called by muse, mutect2, varscan2
- SGK3 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100616868; called by muse, mutect2, varscan2
- SIPA1L2 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 138/159 reads (87%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as COSV99479655; called by muse, mutect2, varscan2
- SLC35B2 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 76/131 reads (58%) | catalogued as rs752392556; called by mutect2, pindel, varscan2
- SLC4A10 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759420527, COSV55768636; called by muse, mutect2, varscan2
- SPTBN1 | c.6434T>G p.V2145G | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1217933047, COSV100443390; called by muse, mutect2, varscan2
- ST18 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV52508982; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | PolyPhen possibly damaging (0.46); catalogued as COSV99398567, COSV99398628; called by muse, varscan2
- ST6GALNAC6 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | PolyPhen benign (0.088); catalogued as COSV99398630; called by muse, varscan2
- STK10 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 58/77 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs755785096, COSV99452273; called by muse, mutect2, varscan2
- STXBP4 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV100178412; called by muse, mutect2, varscan2
- SUCNR1 | c.15+1G>A p.X5_splice | Splice Site (SNP) | VAF 30/99 reads (30%) | catalogued as rs1018193902, COSV100751819; called by muse, mutect2, varscan2
- TBKBP1 | c.411_412del p.C138Rfs*5 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs957924514; called by pindel, varscan2
- TECTA | c.3977A>G p.N1326S | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV99881498; called by muse, mutect2, varscan2
- TNFAIP6 | c.468A>T p.E156D | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99694071; called by muse, mutect2, varscan2
- TOMM70 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs762230068, COSV99424582; called by muse, mutect2, varscan2
- TRAM1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs200901078, COSV99140914; called by muse, mutect2, varscan2
- TTN | c.21248G>C p.S7083T (on ENST00000591111; = p.S6156T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | PolyPhen benign (0.007); catalogued as COSV100629363; called by muse, mutect2, varscan2
- UBC | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | catalogued as COSV60062067; called by muse, mutect2, varscan2
- UNC13C | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV99522816; called by muse, mutect2, varscan2
- WARS2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 95/119 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99346762; called by muse, mutect2, varscan2
- WDR3 | c.2420A>T p.Y807F | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.58); PolyPhen benign (0.231); catalogued as COSV100310538; called by muse, mutect2, varscan2
- WNK2 | c.5812C>T p.R1938W (on ENST00000297954 / NM_001282394.1; = p.R1901W on NM_006648.3) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs768429578, COSV99944513; called by muse, varscan2
- XKR7 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.78); PolyPhen probably damaging (1); catalogued as rs749317124, COSV73813151; called by muse, mutect2, varscan2
- ZNF382 | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53087019; called by muse, mutect2, varscan2
- ZNF804A | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV56447591, COSV56453452; called by muse, mutect2, varscan2
- ACMSD | c.14del p.I5Tfs*13 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- AK9 | c.3016_3017del p.M1006Vfs*17 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP27 | c.1496del p.K499Rfs*34 (on ENST00000428638 / NM_001282290.1; = p.K158Rfs*34 on NM_199282.3) | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- ATP6V1C2 | c.442_443del p.N148Pfs*19 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- COQ8A | c.1757_1759del p.K586del | In Frame Del (DEL) | VAF 16/107 reads (15%) | called by pindel, varscan2
- DAGLB | c.1444del p.Y482Ifs*15 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- DECR2 | c.249_252del p.S84Wfs*17 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- EIF4H | c.327_335del p.S110_R112del | In Frame Del (DEL) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- ITSN1 | c.3584_3586del p.G1195del | In Frame Del (DEL) | VAF 28/40 reads (70%) | called by mutect2, pindel, varscan2
- KMT2D | c.13415_13416del p.V4472Afs*14 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by pindel, varscan2
- RAB12 | c.379_381del p.K127del | In Frame Del (DEL) | VAF 23/146 reads (16%) | called by pindel, varscan2
- STEAP4 | c.1186_1192del p.A396Pfs*25 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.87A>G p.L29= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99254029; called by muse, mutect2, varscan2
- ATG14 | c.63G>T p.P21= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99903016; called by muse, mutect2, varscan2
- AZGP1 | c.582G>T p.L194= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV52798012, COSV99448208; called by muse, mutect2, varscan2
- BIRC5 | c.321A>G p.E107= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs997414386, COSV100051476; called by muse, mutect2, varscan2
- CDH23 | c.1281C>T p.Y427= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as rs1349593079, COSV99823726; ClinVar: likely benign; called by muse, mutect2, varscan2
- GALNT5 | c.2484T>C p.T828= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99375585; called by muse, mutect2, varscan2
- GHSR | c.486G>T p.L162= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV99577244; called by muse, mutect2
- GPR6 | c.738G>A p.V246= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99254555; called by mutect2, varscan2
- GSR | c.648C>T p.S216= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as COSV55319813; called by muse, mutect2, varscan2
- HIPK2 | c.3210G>A p.P1070= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs1224985166, COSV101301661, COSV69212420; called by muse, mutect2, varscan2
- HTR5A | c.96C>T p.S32= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99839977; called by muse, mutect2, varscan2
- IGHV3-30 | c.336G>C p.V112= | Silent (SNP) | VAF 38/407 reads (9%) | catalogued as rs771431417; called by muse, mutect2
- KCNH7 | c.1995T>A p.I665= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as COSV100037719; called by muse, mutect2, varscan2
- KIF21B | c.3501C>T p.S1167= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as rs994006205, COSV59758183; called by muse, mutect2
- MMS22L | c.1149A>G p.V383= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99247711; called by muse, mutect2, varscan2
- PCMTD1 | c.264A>G p.G88= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100859794; called by muse, mutect2
- PFAS | c.3606C>T p.Y1202= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs150119860; called by muse, mutect2, varscan2
- PLLP | c.477C>T p.F159= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV99536172; called by muse, mutect2, varscan2
- PRDM9 | c.1470A>T p.G490= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99691230; called by muse, mutect2, varscan2
- PTCH2 | c.2179C>T p.L727= | Silent (SNP) | VAF 35/43 reads (81%) | catalogued as COSV100942270; called by muse, mutect2, varscan2
- PTH2R | c.519T>C p.H173= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as COSV99782879; called by muse, mutect2, varscan2
- RFC1 | c.3414C>T p.P1138= (on ENST00000381897 / NM_001363496.2; = p.P1137= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as COSV56461521, COSV99975928; called by muse, mutect2, varscan2
- RFX7 | c.3027T>G p.S1009= (on ENST00000559447 / NM_001368074.1; = p.S1106= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100429392; called by muse, mutect2, varscan2
- RMND5B | c.1008C>T p.F336= | Silent (SNP) | VAF 77/96 reads (80%) | catalogued as rs374576631; called by muse, mutect2, varscan2
- SCNN1B | c.1032C>T p.I344= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs148438164; called by muse, mutect2, varscan2
- SIRPB1 | c.345C>G p.A115= | Silent (SNP) | VAF 46/256 reads (18%) | catalogued as COSV53539555, COSV99498578; called by muse, mutect2, varscan2
- SLC12A1 | c.99T>C p.S33= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs769791561, COSV100372580; called by muse, mutect2, varscan2
- SLCO1B1 | c.114T>C p.F38= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99919112; called by muse, mutect2, varscan2
- SMG5 | c.1980C>G p.V660= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as rs760587375, COSV100700923; called by muse, mutect2, varscan2
- SPAG9 | c.1857C>A p.A619= (on ENST00000262013 / NM_001130528.3; = p.A605= on NM_003971.6) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100005968; called by muse, mutect2, varscan2
- SRC | c.99C>T p.P33= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV62439934; called by muse, mutect2, varscan2
- TDRD6 | c.3114C>T p.T1038= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100288343; called by muse, mutect2
- TECRL | c.651G>A p.L217= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV101168783, COSV67085734; called by muse, mutect2, varscan2
- TMEM45A | c.375A>G p.L125= | Silent (SNP) | VAF 14/292 reads (5%) | catalogued as COSV100058373; called by muse, mutect2
- USP28 | c.322T>C p.L108= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as COSV50198059, COSV99136703; called by muse, mutect2, varscan2
- ZFPM2 | c.3330T>C p.G1110= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs775737083, COSV101023544; called by muse, mutect2, varscan2
- ZNF212 | c.168G>A p.E56= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs1466366195, COSV100242462; called by muse, mutect2
- ZNF536 | c.1995C>T p.H665= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100834775, COSV62830115; called by muse, mutect2
- ZNF804A | c.3417C>G p.T1139= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV100170137; called by muse, mutect2, varscan2
- CR1 | c.487+12073A>T | Intron (SNP) | VAF 121/153 reads (79%) | catalogued as COSV100888038; called by muse, mutect2, varscan2
- DENND1A | c.1577+1578T>A | Intron (SNP) | VAF 49/97 reads (51%) | catalogued as COSV101011323; called by muse, mutect2, varscan2
- ELFN2 | c.*1C>A | 3'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as rs897326378, COSV101297642, COSV68744442; called by muse, mutect2, varscan2
- GLRX5 | chr14:95533442 T>C | 5'Flank (SNP) | VAF 86/193 reads (45%) | catalogued as rs1431613872; called by muse, mutect2, varscan2
- NCOA7 | c.2245-1614G>A | Intron (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- SCN3A | c.603-131G>C | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99327748, COSV99328473; called by muse, mutect2, varscan2
- WWP2 | c.1683-841C>T | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs1488291496, COSV100598764; called by muse, mutect2, varscan2
